Somatic mutation profile of tumor specimen TARGET-10-PARTGW-09A (aliquot TARGET-10-PARTGW-09A-01D) from TARGET case TARGET-10-PARTGW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,850 days).
Specimen TARGET-10-PARTGW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f3d87c9-331d-4f39-8d48-0f656224f8d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTGW-10A (Blood Derived Normal), aliquot TARGET-10-PARTGW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c173a110-8d65-4b13-8abe-a1a8184a60ef

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'UTR 2, Silent 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLDN16 | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1312164, COSV53228138; called by muse, mutect2, varscan2
- MYO1F | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs774935688; called by muse, mutect2, varscan2
- RGL3 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as rs200532104; called by muse, mutect2, varscan2
- AFAP1L2 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2
- AHNAK | c.11462G>A p.G3821D | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTPS2 | c.1481A>T p.Q494L | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2 | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPI1 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- SPOCK3 | c.966C>A p.S322R | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DST | c.16233T>C p.T5411= (on ENST00000361203 / NM_001374722.1; = p.T2999= on NM_015548.5) | Silent (SNP) | VAF 14/145 reads (10%) | catalogued as rs1166852452, COSV99760368; called by muse, mutect2, varscan2
- DEPDC5 | c.*897G>A | 3'UTR (SNP) | VAF 81/166 reads (49%) | catalogued as rs1229311796; called by muse, mutect2, varscan2
- LMO7 | c.773-68del | Intron (DEL) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- PASK | c.*3A>T | 3'UTR (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- VPS26C | chr21:37221333 C>T | 3'Flank (SNP) | VAF 35/111 reads (32%) | catalogued as rs993394124; called by muse, mutect2, varscan2
